Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5190, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5190-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Original Rep

Date of Amendment

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal mass.

CGA - BP - 5190

Specimens Submitted:

- 1: SP: Kidney, right; partial nephrectomy
- 2: SP: Soft tissue, right peritumoral fat; excision
- 3: SP: Kidney, right lower pole cortex of renal mass; biopsy
- 4: SP: Proximal right distal ureter; excision

AMENDED DIAGNOSIS:

1. SP: Kidney, right; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 4.0 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Shows focal glomerulosclerosis

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: Immunostains show diffuse cytoplasmic membranous pattern of CA IX expression in the tumor cells, which are negative for CK7, c-KIT and racemase. This immunoprofile supports the diagnosis.

[page 2 of 4]
2. SP: Soft tissue, right peritumoral fat; excision:
Benign fibroadipose tissue.

3. SP: Kidney, right lower pole cortex of renal mass; biopsy:
Benign renal cortical parenchyma with focal glomerulosclerosis.

4. SP: Proximal right ureter; excision:
Benign partially denuded urothelium and urethral wall

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED] That report is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT:

Specimens Submitted:

4: SP: Proximal right distal urethra; excision

Gross Description:

4). The specimen is received in formalin labeled "Proximal right distal urethra".

AMENDED REPORT:

Specimens Submitted:

4: SP: Proximal right ureter; excision

Gross Description:

4). The specimen is received in formalin labeled "Proximal right ureter".

The responsible clinician has been notified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CA-1X.	
	CK7	
	NEG CONT	
	IMM RECUT	
	RACEMASE	
	CD117	

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "right renal tumor/stitch marks surgical deep margin". It consists of a 6.5 x 5.0 x 4.0 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a 4.0 x 3.3 x 2.0 cm, soft, yellow-tan mass. The clearance from the resection

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

margin is 0.1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for [REDACTED]

Summary of sections:

FSC - frozen section control

T - tumor

TM - tumor with margin

TK - tumor with uninvolved kidney

2). The specimen is received fresh, labeled "Right peritumoral fat/kidney". It consists of multiple pieces of lobulated yellow-tan fatty tissue measuring 15 x 11 x 3 cm in aggregate. Cut section through the specimen does not reveal any discrete abnormalities. Representative sections are submitted.

Summary of sections:

U-undesignated

3). The specimen is received in formalin, labeled "Right lower pole cortex of renal mass". It consists of a partially cauterized piece of brown-tan renal parenchyma measuring 1.5 x 0.9 x 0.4 cm. The cauterized surface is inked black. The specimen is sectioned and submitted entirely.

Summary of sections:

U-undesignated

4). The specimen is received in formalin labeled "Proximal right distal ureter". It consists of two pieces of yellow-tan soft tissue measuring 0.8 x 0.8 x 0.4 cm in aggregate. The specimen is entirely submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Kidney, right; partial nephrectomy

Block	Sect. Site	PCs
5	ADD	7
1	fsc	1
2	t	2
1	tk	1
2	tm	2

Part 2: SP: Soft tissue, right peritumoral fat; excision

Block	Sect. Site	PCs
1	U	1

Part 3: SP: Kidney, right lower pole cortex of renal mass; biopsy

Block	Sect. Site	PCs
1	u	1

Part 4: SP: Proximal right distal ureter; excision

Block	Sect. Site	PCs
1	U	1

Amendments

[page 4 of 4]
Amend Date: [REDACTED] Amended By: [REDACTED]

Original Diagnosis:

1. SP: Kidney, right; partial nephrectomy:

Tumor Type: Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade: ~~Nuclear grade III/IV~~

Tumor Size: Greatest diameter is 4.0 cm.

Local Invasion (for renal cortical types):
Not identified

Renal Vein Invasion:
Not identified

Surgical Margins:
Free of tumor

Non-Neoplastic Kidney:
Shows focal glomerulosclerosis

Adrenal Gland:
Not identified

Lymph Nodes:
Not identified

Staging for renal cell carcinoma/oncocytoma:
pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

Comment: Immunostains show diffuse cytoplasmic membranous pattern of CA IX expression in the tumor cells, which are negative for CK7, c-KIT and racemase. This immunoprofile supports the diagnosis.

2. SP: Soft tissue, right peritumoral fat; excision:
Benign fibroadipose tissue.

3. SP: Kidney, right lower pole cortex of renal mass; biopsy:
Benign renal cortical parenchyma with focal glomerulosclerosis

4. SP: Proximal right distal urethra; excision:
Benign partially denuded urothelium and urethral wall

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

Source: NCI Genomic Data Commons file 0a3a81f2-f01a-4b79-9516-19bb1cc95518 (TCGA-BP-5190.57D7108F-0A36-4156-81BE-DEF08D506602.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).